Gene-level copy-number profile of tumor specimen C3L-04844-01 from CPTAC case C3L-04844, project CPTAC-3 (Tonsil — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,268 days).
Specimen C3L-04844-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tonsil; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 84ce173a-af9e-40e5-aa96-495ac2f7ae9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04844-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/741f29f8-c602-4d00-bbd6-d3f099604504

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 912; copy number 2: 19,427; copy number 3: 18,844; copy number 4: 17,292; copy number 5: 665; copy number 6: 1,095; copy number 8: 1; copy number 9: 40; copy number 10: 3; copy number 12: 13; copy number 14: 6; copy number 18: 24; copy number 19: 16; copy number 20: 9; copy number 29: 16.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:416,118–416,537, 1 gene (within-gene range 0–2): AC092574.1.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr22:18,527,802–18,530,573, 1 gene: TMEM191B.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 128 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:118,950,386–120,750,337, 8 genes, copy number 10–14 (within-gene range 1–14): AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P.
- chr7:122,144,405–123,230,741, 16 genes, copy number 19: AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1.
- chr7:129,830,732–132,648,688, 62 genes, copy number 9–18 (broad region; genes not listed).
- chr9:39,748,514–39,810,097, 2 genes, copy number 9: GLIDR, BX664615.1.
- chr11:68,870,664–70,189,528, 38 genes, copy number 12–29 (within-gene range 5–29): LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2.
- chr16:32,439,069–32,441,159, 1 gene, copy number 10: PABPC1P13.
- chr22:18,715,815–18,719,341, 1 gene, copy number 8: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
